Somatic mutation profile of tumor specimen C3N-01366-02 (aliquot CPT0093510009) from CPTAC case C3N-01366, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.3 years (23,121 days).
Specimen C3N-01366-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b119046d-25dc-4aa6-9a27-010ea9727d78.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01366-31 (Blood Derived Normal), aliquot CPT0093540002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e099623-7f05-4dd4-9ca6-bae0ca92c67c

The open-access MAF lists 84 somatic variants for this specimen: 50 protein-altering or splice-affecting, 23 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 23, Intron 4, RNA 3, Nonsense Mutation 2, Frame Shift Del 2, 3'UTR 2, 5'Flank 2, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 147/244 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786204929, CM122894, COSV64288557, COSV64309376; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BICDL1 | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0.011); catalogued as rs781251281; called by muse, mutect2, varscan2
- BIRC6 | c.12145G>A p.G4049S | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as rs758549232, COSV66042904; called by muse, mutect2, varscan2
- CCDC158 | c.1573C>T p.R525W | Missense Mutation (SNP) | VAF 137/315 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756093518; called by muse, mutect2, varscan2
- CTAGE1 | c.2021C>T p.P674L | Missense Mutation (SNP) | VAF 123/351 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as rs1486039581, COSV66943137; called by muse, mutect2, varscan2
- CUL2 | c.119+1G>A p.X40_splice | Splice Site (SNP) | VAF 35/95 reads (37%) | catalogued as COSV66079733; called by muse, mutect2, varscan2
- FBN3 | c.3502G>A p.V1168M | Missense Mutation (SNP) | VAF 64/169 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV54459954; called by muse, mutect2, varscan2
- HMG20B | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 60/137 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as rs545353983; called by muse, mutect2, varscan2
- ISM1 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 163/438 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs768775917, COSV52606566; called by muse, mutect2, varscan2
- ITGAD | c.2858G>A p.R953H | Missense Mutation (SNP) | VAF 77/212 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as rs761068465, COSV99791457; called by muse, mutect2, varscan2
- KCP | c.1465G>A p.E489K (on ENST00000620378; = p.E546K on NM_001366122.1) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.99); catalogued as rs987756214; called by muse, mutect2
- KIAA1549L | c.4763C>T p.S1588L (on ENST00000321505; = p.S1885L on NM_012194.3) | Missense Mutation (SNP) | VAF 102/255 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as rs374441782; called by muse, mutect2, varscan2
- KLK12 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 101/263 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.035); catalogued as rs145107386; called by muse, mutect2, varscan2
- LCN8 | c.253G>A p.V85M (on ENST00000612714 / NM_001345934.1; = p.V62M on NM_178469.3) | Missense Mutation (SNP) | VAF 71/157 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV60209305; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1763C>T p.P588L | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1161809995, COSV51717944; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3256C>T p.R1086W | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770880471; called by muse, mutect2, varscan2
- MECOM | c.614G>A p.R205H (on ENST00000468789 / NM_001105078.4; = p.R393H on NM_004991.4) | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52964033, COSV52965020; called by muse, mutect2, varscan2
- MS4A6E | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 81/218 reads (37%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs761819409, COSV55726728, COSV55728023; called by muse, varscan2
- MYH2 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 131/536 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs183147747, COSV55443582; called by muse, mutect2, varscan2
- NFASC | c.230G>A p.R77Q (on ENST00000339876 / NM_001378329.1; = p.R71Q on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/268 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs757003214, COSV58365309; called by muse, mutect2, varscan2
- OR4K15 | c.337C>T p.R113C (on ENST00000305051; = p.R89C on NM_001005486.1) | Missense Mutation (SNP) | VAF 91/257 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs201446213, COSV59301399; called by muse, mutect2, varscan2
- POTEE | c.2705C>A p.T902N | Missense Mutation (SNP) | VAF 251/1102 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.097); catalogued as rs775426284; called by muse, varscan2
- PRDM16 | c.1027G>A p.V343M | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.934); catalogued as rs1373495544; called by muse, mutect2
- RASGEF1C | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 61/176 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV63182380; called by muse, mutect2, varscan2
- RNF212 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as rs781502373, COSV67113748, COSV67114894; called by muse, mutect2, varscan2
- SVEP1 | c.8524G>A p.G2842S | Missense Mutation (SNP) | VAF 107/278 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.045); catalogued as rs990247145, COSV52845085; called by muse, mutect2, varscan2
- TMC7 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.696); catalogued as rs752282682, COSV100432596; called by muse, mutect2, varscan2
- TP53BP2 | c.428G>A p.R143H (on ENST00000343537 / NM_001031685.3; = p.R14H on NM_005426.2) | Missense Mutation (SNP) | VAF 76/210 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs766049032, COSV100636849; called by muse, mutect2, varscan2
- TRIB3 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 160/364 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs761852047, COSV53931135; called by muse, mutect2, varscan2
- USP7 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 128/318 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs775166718; called by muse, varscan2
- UTS2R | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 71/246 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs913669442, COSV57454041; called by muse, mutect2, varscan2
- ZBED1 | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 128/318 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58136154; called by muse, mutect2, varscan2
- A2ML1 | c.2170G>T p.A724S | Missense Mutation (SNP) | VAF 51/189 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BNIPL | c.897_898del p.W299* | Nonsense Mutation (DEL) | VAF 91/327 reads (28%) | called by mutect2, pindel, varscan2
- CACNA1A | c.7351T>G p.S2451A | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCNQ | c.238G>C p.A80P | Missense Mutation (SNP) | VAF 163/212 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CRNN | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 112/276 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DSG4 | c.2165G>A p.G722E | Missense Mutation (SNP) | VAF 108/301 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- DUSP10 | c.893del p.G298Afs*49 | Frame Shift Del (DEL) | VAF 21/58 reads (36%) | called by mutect2, pindel
- FADS3 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FAM200B | c.1420C>T p.L474F | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FUT8 | c.673C>T p.H225Y (on ENST00000360689 / NM_001371534.1; = p.H62Y on NM_004480.4) | Missense Mutation (SNP) | VAF 121/316 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MEP1A | c.1937G>A p.G646E | Missense Mutation (SNP) | VAF 124/332 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- NCAM2 | c.2177T>C p.I726T | Missense Mutation (SNP) | VAF 56/216 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PNISR | c.742C>T p.Q248* | Nonsense Mutation (SNP) | VAF 54/137 reads (39%) | called by muse, mutect2, varscan2
- RTL1 | c.344G>A p.S115N | Missense Mutation (SNP) | VAF 96/230 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPDL1 | c.1454del p.E485Gfs*10 | Frame Shift Del (DEL) | VAF 119/386 reads (31%) | called by mutect2, pindel, varscan2
- SRFBP1 | c.241_243del p.D81del | In Frame Del (DEL) | VAF 54/146 reads (37%) | called by pindel, varscan2
- TMEM272 | c.227C>T p.T76I | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by mutect2, varscan2
- XKR4 | c.1436A>T p.K479M | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- ADAM33 | c.1053C>T p.L351= | Silent (SNP) | VAF 60/123 reads (49%) | catalogued as rs746535429; called by muse, mutect2, varscan2
- ANKRD52 | c.354G>T p.R118= | Silent (SNP) | VAF 95/234 reads (41%) | called by muse, mutect2, varscan2
- BAIAP2L1 | c.822C>T p.Y274= | Silent (SNP) | VAF 40/189 reads (21%) | catalogued as rs756426782, COSV50055242; called by muse, mutect2, varscan2
- CCNQ | c.240C>T p.A80= | Silent (SNP) | VAF 162/212 reads (76%) | called by muse, mutect2
- CDH17 | c.300C>T p.D100= | Silent (SNP) | VAF 46/144 reads (32%) | catalogued as rs747266533, COSV50345797; called by muse, mutect2, varscan2
- CLIP2 | c.768C>T p.P256= | Silent (SNP) | VAF 50/188 reads (27%) | catalogued as COSV99791364; called by muse, mutect2, varscan2
- COL4A1 | c.96T>C p.A32= | Silent (SNP) | VAF 137/394 reads (35%) | called by muse, mutect2, varscan2
- CYP2A13 | c.595C>T p.L199= | Silent (SNP) | VAF 95/269 reads (35%) | called by muse, mutect2, varscan2
- DHCR7 | c.1314C>T p.I438= | Silent (SNP) | VAF 191/491 reads (39%) | called by muse, mutect2, varscan2
- FAM189A1 | c.570G>A p.V190= | Silent (SNP) | VAF 97/300 reads (32%) | catalogued as rs1424147825, COSV54266883; called by muse, mutect2, varscan2
- FLII | c.1971C>T p.Y657= | Silent (SNP) | VAF 125/478 reads (26%) | catalogued as rs112683318; called by muse, mutect2, varscan2
- FLNB | c.5256G>T p.P1752= | Silent (SNP) | VAF 139/392 reads (35%) | catalogued as COSV55878287; called by muse, mutect2, varscan2
- GABRR1 | c.210G>A p.S70= | Silent (SNP) | VAF 55/139 reads (40%) | catalogued as rs371490411; called by muse, mutect2, varscan2
- JPH1 | c.504C>T p.S168= | Silent (SNP) | VAF 16/177 reads (9%) | called by muse, mutect2
- KCNS3 | c.1074C>T p.P358= | Silent (SNP) | VAF 77/192 reads (40%) | called by muse, mutect2, varscan2
- LRIG2 | c.507T>C p.L169= | Silent (SNP) | VAF 52/102 reads (51%) | called by muse, mutect2, varscan2
- PCDHA6 | c.1863G>A p.P621= | Silent (SNP) | VAF 147/357 reads (41%) | catalogued as rs782199993, COSV65343457; called by muse, mutect2, varscan2
- PDGFRA | c.21G>A p.A7= | Silent (SNP) | VAF 579/844 reads (69%) | catalogued as rs200090515, COSV99955876; ClinVar: likely benign; called by muse, mutect2, varscan2
- PDHX | c.513C>T p.V171= | Silent (SNP) | VAF 61/200 reads (31%) | called by muse, mutect2, varscan2
- PELP1 | c.2370C>A p.I790= | Silent (SNP) | VAF 160/256 reads (63%) | called by muse, mutect2, varscan2
- PRPF8 | c.723G>A p.L241= | Silent (SNP) | VAF 345/647 reads (53%) | called by muse, mutect2, varscan2
- RFPL4A | c.24C>T p.I8= | Silent (SNP) | VAF 22/90 reads (24%) | called by muse, mutect2, varscan2
- TSPAN16 | c.372C>T p.F124= | Silent (SNP) | VAF 77/185 reads (42%) | catalogued as rs1262027339, COSV100368271, COSV57441943; called by muse, mutect2, varscan2
- CMAHP | n.1043T>C | RNA (SNP) | VAF 35/68 reads (51%) | called by muse, mutect2, varscan2
- DNAJB5 | c.*55C>T | 3'UTR (SNP) | VAF 106/242 reads (44%) | called by muse, mutect2, varscan2
- HDAC4 | c.1776+30_1776+58del | Intron (DEL) | VAF 29/93 reads (31%) | called by mutect2, pindel, varscan2
- MIR9-1HG | n.126+12_126+14del | Intron (DEL) | VAF 36/106 reads (34%) | called by mutect2, pindel, varscan2
- PPM1L | c.399+85581C>T | Intron (SNP) | VAF 77/213 reads (36%) | called by muse, mutect2, varscan2
- PTGES2 | chr9:128128794 C>A | 5'Flank (SNP) | VAF 150/394 reads (38%) | called by muse, mutect2, varscan2
- RALGAPA1 | c.*70G>A | 3'UTR (SNP) | VAF 81/232 reads (35%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159728 C>T | 5'Flank (SNP) | VAF 66/166 reads (40%) | called by muse, mutect2, varscan2
- TMPRSS11BNL | n.193G>C | RNA (SNP) | VAF 32/92 reads (35%) | called by muse, mutect2, varscan2
- TMTC1 | c.939-27502C>A | Intron (SNP) | VAF 24/41 reads (59%) | called by muse, mutect2, varscan2
- TUBB7P | n.1280C>T | RNA (SNP) | VAF 74/162 reads (46%) | catalogued as rs782387517; called by muse, mutect2, varscan2
